Somatic mutation profile of tumor specimen TCGA-3A-A9IJ-01A (aliquot TCGA-3A-A9IJ-01A-11D-A397-08) from TCGA case TCGA-3A-A9IJ, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroendocrine carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IB; Tumor grade: G1; Age at diagnosis: 65.1 years (23,791 days).
Specimen TCGA-3A-A9IJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) acd92fbd-98e9-41a2-9a9a-2862924936bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3A-A9IJ-10A (Blood Derived Normal), aliquot TCGA-3A-A9IJ-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94f22f04-ce73-4374-8fff-c7d6917ed19c

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 10, Silent 6, Splice Site 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DSCAM | c.1060C>A p.L354I | Missense Mutation (SNP) | VAF 59/1701 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs866741435, COSV101261293; called by muse, mutect2
- H1-4 | c.363A>T p.K121N | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV99175345; called by muse, mutect2
- H1-4 | c.364A>T p.K122* | Nonsense Mutation (SNP) | VAF 18/176 reads (10%) | catalogued as COSV99175346; called by muse, mutect2
- IL6ST | c.1699+1G>T p.X567_splice | Splice Site (SNP) | VAF 45/141 reads (32%) | catalogued as COSV100410998, COSV61142903; called by muse, mutect2, varscan2
- IQCJ | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 26/766 reads (3%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV67332822; called by muse, mutect2
- KLHL36 | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.234); catalogued as rs767162985, COSV50725813; called by muse, mutect2, varscan2
- ORMDL3 | c.324G>T p.V108= | Splice Region (SNP) | VAF 26/613 reads (4%) | catalogued as COSV100401572; called by muse, mutect2
- PRPF8 | c.4780T>C p.C1594R | Missense Mutation (SNP) | VAF 907/2297 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV100517817; called by muse, mutect2, varscan2
- ROBO2 | c.2754T>A p.D918E | Missense Mutation (SNP) | VAF 86/712 reads (12%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.53); catalogued as COSV100169276; called by muse, mutect2, varscan2
- SOX10 | c.1289C>T p.P430L | Missense Mutation (SNP) | VAF 11/333 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100704140; called by muse, mutect2
- TMC7 | c.1876C>T p.P626S | Missense Mutation (SNP) | VAF 137/346 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as rs199702842, COSV100432760, COSV58583408; called by muse, mutect2, varscan2
- YWHAE | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 182/496 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as rs777592060, COSV51981020; called by muse, mutect2, varscan2
- GRIN2B | c.3233C>T p.A1078V | Missense Mutation (SNP) | VAF 11/237 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.554); called by muse, mutect2
- ABCC2 | c.450G>T p.L150= | Silent (SNP) | VAF 129/314 reads (41%) | catalogued as COSV100965644, COSV64970871; called by muse, mutect2, varscan2
- BANK1 | c.642C>T p.F214= | Silent (SNP) | VAF 28/278 reads (10%) | catalogued as COSV59845355; called by muse, mutect2, varscan2
- COX16 | c.48C>T p.L16= | Silent (SNP) | VAF 16/340 reads (5%) | catalogued as COSV101112183, COSV66303078; called by muse, mutect2
- CYP1A1 | c.987C>T p.S329= | Silent (SNP) | VAF 45/321 reads (14%) | catalogued as COSV101122372; called by muse, mutect2, varscan2
- HSF4 | c.273G>A p.L91= | Silent (SNP) | VAF 9/169 reads (5%) | called by muse, mutect2
- INTS6 | c.1245T>C p.Y415= | Silent (SNP) | VAF 15/343 reads (4%) | catalogued as COSV100247212; called by muse, mutect2
